Somatic mutation profile of tumor specimen TARGET-20-PASXAH-09A (aliquot TARGET-20-PASXAH-09A-01D) from TARGET case TARGET-20-PASXAH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,410 days).
Specimen TARGET-20-PASXAH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfe45212-8be3-4936-b679-08e222b13817.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASXAH-14A (Bone Marrow Normal), aliquot TARGET-20-PASXAH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55f15128-42b3-4d89-b6fc-a13f2aad2355

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.5737C>T p.R1913* | Nonsense Mutation (SNP) | VAF 51/110 reads (46%) | catalogued as rs1554237658, COSV51675024; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 60/133 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ETV6 | c.770_771insGTAGCTCATCCAG p.S257Rfs*2 | Nonsense Mutation (INS) | VAF 30/87 reads (34%) | called by mutect2, varscan2
